Somatic mutation profile of tumor specimen TARGET-30-PATNWL-01A (aliquot TARGET-30-PATNWL-01A-01D) from TARGET case TARGET-30-PATNWL, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.9 years (1,794 days).
Specimen TARGET-30-PATNWL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 151933ee-d98f-4746-907e-3b856bf49d4a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATNWL-10A (Blood Derived Normal), aliquot TARGET-30-PATNWL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db4669ab-cbcb-4ff3-a766-3a887aed8f6c

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55257982, COSV99808532; called by muse, mutect2, varscan2
- NRXN1 | c.3535G>T p.E1179* | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- CNKSR1 | c.*63C>A | 3'UTR (SNP) | VAF 77/152 reads (51%) | catalogued as COSV58795155; called by muse, mutect2, varscan2
